Somatic mutation profile of tumor specimen ALCH-B3F5-TTP1-A (aliquot ALCH-B3F5-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3F5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.8 years (26,578 days).
Specimen ALCH-B3F5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73085446-500e-4351-b216-768b872d4dcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3F5-NB1-A (Blood Derived Normal), aliquot ALCH-B3F5-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8d08046-0e8e-4ccd-9a6b-2028cc527ef2

The open-access MAF lists 541 somatic variants for this specimen: 372 protein-altering or splice-affecting, 104 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 312, Silent 104, Intron 26, Nonsense Mutation 22, Splice Site 17, 5'UTR 10, 3'UTR 9, RNA 7, Splice Region 7, 3'Flank 7, Frame Shift Del 6, 5'Flank 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMEM67 | c.888G>T p.W296C | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs386834208, CM094693; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 161/502 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAM2 | c.2175-2A>C p.X725_splice | Splice Site (SNP) | VAF 79/314 reads (25%) | catalogued as COSV55862974; called by muse, mutect2, varscan2
- ADGRF4 | c.245dup p.W83Vfs*6 | Frame Shift Ins (INS) | VAF 138/630 reads (22%) | catalogued as rs764604854; called by mutect2, varscan2
- ADGRV1 | c.4222A>G p.T1408A | Missense Mutation (SNP) | VAF 137/443 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs777761619; called by muse, mutect2, varscan2
- ALX4 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as rs762716140, COSV61328413; called by muse, mutect2, varscan2
- ANGPTL4 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1412783203, COSV56845369; called by muse, mutect2, varscan2
- ANKRD31 | c.4263dup p.Q1422Tfs*12 | Frame Shift Ins (INS) | VAF 39/135 reads (29%) | catalogued as rs530301594; called by mutect2, varscan2
- ANKUB1 | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 52/842 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs755269424, COSV67167236; called by muse, mutect2
- ATP13A5 | c.2902C>T p.L968F | Missense Mutation (SNP) | VAF 125/549 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs569739870; called by muse, mutect2, varscan2
- AXIN2 | c.1713C>T p.G571= | Splice Region (SNP) | VAF 43/581 reads (7%) | catalogued as rs761978806; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- BCAR1 | c.1453G>T p.G485C | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.845); catalogued as COSV50779840; called by muse, mutect2, varscan2
- BCHE | c.1518G>T p.G506= | Splice Region (SNP) | VAF 47/417 reads (11%) | catalogued as rs755486397; called by muse, mutect2, varscan2
- BCLAF1 | c.2649C>A p.S883R | Missense Mutation (SNP) | VAF 223/855 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs760737910; called by muse, mutect2, varscan2
- BMP5 | c.326C>A p.T109N | Missense Mutation (SNP) | VAF 210/685 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs756759592; called by muse, mutect2, varscan2
- BRINP1 | c.830A>C p.N277T | Missense Mutation (SNP) | VAF 43/879 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV56292560, COSV56297328; called by muse, mutect2
- CADM2 | c.139G>T p.D47Y (on ENST00000407528 / NM_001167674.2; = p.D49Y on NM_153184.4) | Missense Mutation (SNP) | VAF 100/646 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV67405529; called by muse, mutect2, varscan2
- CCDC60 | c.966C>T p.P322= | Splice Region (SNP) | VAF 59/341 reads (17%) | catalogued as rs1300612688; called by muse, mutect2, varscan2
- CEP83 | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60409189; called by muse, mutect2, varscan2
- CHD9 | c.546C>G p.N182K | Missense Mutation (SNP) | VAF 80/403 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as rs1460763562; called by muse, mutect2, varscan2
- CIAO3 | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 111/383 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1347275217; called by muse, mutect2, varscan2
- CNTN1 | c.2534G>C p.W845S | Missense Mutation (SNP) | VAF 159/733 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61637647; called by muse, mutect2, varscan2
- COL11A1 | c.4213G>C p.G1405R | Missense Mutation (SNP) | VAF 324/1202 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376137502; called by muse, mutect2, varscan2
- COL22A1 | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV57327929; called by muse, mutect2, varscan2
- COL24A1 | c.2314T>A p.F772I | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65308269; called by muse, varscan2
- COL4A3 | c.2983C>A p.P995T | Missense Mutation (SNP) | VAF 366/1085 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.341); catalogued as COSV59258359; called by muse, mutect2, varscan2
- CPA5 | c.198G>A p.K66= | Splice Region (SNP) | VAF 70/342 reads (20%) | catalogued as rs1470378617; called by muse, mutect2, varscan2
- CSMD1 | c.4580C>G p.A1527G (on ENST00000520002; = p.A1526G on NM_033225.6) | Missense Mutation (SNP) | VAF 176/434 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59296859; called by muse, mutect2, varscan2
- CTAGE1 | c.1592del p.P531Qfs*21 | Frame Shift Del (DEL) | VAF 63/424 reads (15%) | catalogued as COSV66943393; called by mutect2, pindel, varscan2
- CYP21A2 | c.1280G>T p.R427L | Missense Mutation (SNP) | VAF 104/581 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM013360, CM110246; called by muse, mutect2, varscan2
- DAAM2 | c.290G>T p.S97I | Missense Mutation (SNP) | VAF 145/564 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208065815; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 35/270 reads (13%) | catalogued as rs754135731; called by muse*, mutect2, varscan2*
- DNAH5 | c.3082G>T p.E1028* | Nonsense Mutation (SNP) | VAF 268/827 reads (32%) | catalogued as COSV54218086, COSV99448639; called by muse, mutect2, varscan2
- DNAJC1 | c.1439G>A p.S480N | Missense Mutation (SNP) | VAF 67/1216 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV65414437, COSV65414857; called by muse, mutect2
- DSCAML1 | c.1394-1G>A p.X465_splice (on ENST00000321322; = p.X405_splice on NM_020693.4) | Splice Site (SNP) | VAF 66/248 reads (27%) | catalogued as COSV100357020; called by muse, mutect2, varscan2
- ELFN2 | c.1259G>T p.R420L | Missense Mutation (SNP) | VAF 142/431 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537816334, COSV68744131; called by muse, mutect2, varscan2
- ERN1 | c.1304C>A p.A435D | Missense Mutation (SNP) | VAF 59/395 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs201598988; called by muse, mutect2, varscan2
- ETV6 | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 71/554 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56766214; called by muse, mutect2, varscan2
- F9 | c.1083C>A p.H361Q | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99496636; called by muse, mutect2, varscan2
- FBXO10 | c.1658A>G p.N553S | Missense Mutation (SNP) | VAF 363/762 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1178233254; called by muse, mutect2, varscan2
- FBXO34 | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100571996; called by muse, mutect2, varscan2
- FOCAD | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as rs747448535; called by muse, mutect2, varscan2
- FUT1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV59567581; called by muse, mutect2
- GAP43 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV99043467; called by muse, mutect2
- GDF7 | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99694265; called by muse, mutect2, varscan2
- GLT8D2 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 70/207 reads (34%) | catalogued as rs757478066; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 216/823 reads (26%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1179286746; called by muse, mutect2, varscan2
- GPATCH2 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 174/912 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1477122635; called by muse, mutect2, varscan2
- HCN1 | c.1961C>A p.T654K | Missense Mutation (SNP) | VAF 366/1578 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as COSV57498316; called by muse, varscan2
- HOXD13 | c.119G>T p.C40F | Missense Mutation (SNP) | VAF 104/171 reads (61%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1213904610; called by muse, mutect2, varscan2
- HSD17B2 | c.758G>A p.W253* | Nonsense Mutation (SNP) | VAF 75/598 reads (13%) | catalogued as rs543111518; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 144/437 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs200419221, COSV56242588, COSV56281020; called by muse, mutect2, varscan2
- INTS2 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 146/521 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52156085; called by muse, mutect2, varscan2
- ITPRID1 | c.214G>T p.V72F | Missense Mutation (SNP) | VAF 63/390 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs372723381; called by muse, mutect2, varscan2
- KALRN | c.1349T>A p.L450Q | Missense Mutation (SNP) | VAF 48/753 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV104384088; called by muse, mutect2
- KCNK13 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 195/530 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs150186575, COSV99965875; called by muse, mutect2, varscan2
- KIF16B | c.2284G>T p.V762L | Missense Mutation (SNP) | VAF 163/818 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs752435760, COSV61710618; called by muse, mutect2, varscan2
- LHCGR | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 116/800 reads (15%) | catalogued as COSV99683922; called by muse, mutect2, varscan2
- LRIT1 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 209/578 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.277); catalogued as COSV64512726; called by muse, mutect2, varscan2
- MAP1B | c.7031C>T p.T2344M | Missense Mutation (SNP) | VAF 91/226 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs371612577; called by muse, mutect2, varscan2
- MBIP | c.715A>G p.M239V | Missense Mutation (SNP) | VAF 74/372 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs776788927; called by muse, mutect2, varscan2
- MED25 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 135/837 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100457886; called by muse, mutect2, varscan2
- MRTFB | c.2864G>T p.R955L (on ENST00000571589 / NM_001365412.2; = p.R905L on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 248/894 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100371746; called by muse, mutect2, varscan2
- MSR1 | c.149A>G p.K50R | Missense Mutation (SNP) | VAF 106/1028 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs761566052; called by muse, mutect2
- MUC4 | c.11413C>G p.Q3805E | Missense Mutation (SNP) | VAF 136/1762 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.017); catalogued as rs1415703453; called by muse, varscan2
- MYBPC3 | c.1678G>T p.D560Y | Missense Mutation (SNP) | VAF 64/449 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV57029057; called by muse, mutect2, varscan2
- NFKBIE | c.139C>A p.R47S | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1396486702; called by muse, mutect2, varscan2
- OGDH | c.1852G>C p.G618R | Missense Mutation (SNP) | VAF 106/436 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56055574; called by muse, mutect2, varscan2
- OR14A2 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 46/317 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.878); catalogued as COSV100825523; called by muse, mutect2, varscan2
- OR2B11 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 90/301 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs767670480; called by muse, mutect2, varscan2
- OR2G6 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 87/345 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs146486539; called by muse, mutect2, varscan2
- OR4C15 | c.707C>A p.P236Q (on ENST00000314644; = p.P182Q on NM_001001920.2) | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV58950833; called by muse, mutect2, varscan2
- OR8H2 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 51/499 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs937828693; called by muse, mutect2, varscan2
- OR9Q2 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 58/712 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100285545; called by muse, mutect2
- PAX5 | c.42G>C p.R14S | Missense Mutation (SNP) | VAF 110/2976 reads (4%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.879); catalogued as COSV63906355; called by muse, mutect2
- PCDH11X | c.3451G>T p.A1151S | Missense Mutation (SNP) | VAF 472/1026 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53494953; called by muse, mutect2, varscan2
- PCNX3 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 64/501 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373871960; called by muse, mutect2, varscan2
- PDLIM5 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs903453897, COSV58747169; called by muse, mutect2
- PLXND1 | c.2753G>T p.R918L | Missense Mutation (SNP) | VAF 249/779 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs767215800; called by muse, mutect2, varscan2
- PNPLA5 | c.492+1G>A p.X164_splice | Splice Site (SNP) | VAF 29/138 reads (21%) | catalogued as rs1335021590; called by muse, mutect2, varscan2
- PRPS1L1 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 81/433 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs1255822982, COSV72649951; called by muse, mutect2, varscan2
- PRR16 | c.416G>T p.R139M (on ENST00000407149 / NM_001300783.2; = p.R116M on NM_016644.2) | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.318); catalogued as COSV101087299; called by muse, mutect2, varscan2
- PXMP4 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 128/342 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV54133999; called by muse, mutect2, varscan2
- RAB3GAP2 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 152/623 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV52965329; called by muse, mutect2, varscan2
- RFX6 | c.2299C>T p.H767Y | Missense Mutation (SNP) | VAF 47/385 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV100263494; called by muse, mutect2, varscan2
- RGS7 | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 120/625 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.957); catalogued as rs1207358094, COSV100466835, COSV100469032; called by muse, mutect2, varscan2
- RXFP1 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 136/611 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs368183339; called by muse, mutect2, varscan2
- RYR2 | c.4010A>G p.Y1337C | Missense Mutation (SNP) | VAF 117/760 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.258); catalogued as rs765369749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.5098G>T p.A1700S | Missense Mutation (SNP) | VAF 145/822 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs1367432544, COSV63711958; called by muse, mutect2, varscan2
- SCN2A | c.5047G>T p.A1683S | Missense Mutation (SNP) | VAF 273/783 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as rs764538126; called by muse, mutect2, varscan2
- SFMBT2 | c.962C>A p.S321* | Nonsense Mutation (SNP) | VAF 135/350 reads (39%) | catalogued as COSV62813757; called by muse, mutect2, varscan2
- SLC22A24 | c.902G>C p.R301T | Missense Mutation (SNP) | VAF 88/346 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV70301156, COSV70302909; called by muse, mutect2, varscan2
- SLC3A2 | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.359); catalogued as COSV100785003; called by muse, mutect2, varscan2
- SLC6A3 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 84/538 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs746715018, COSV99548940; called by muse, mutect2, varscan2
- SMR3B | c.97G>C p.G33R | Missense Mutation (SNP) | VAF 26/558 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100513475; called by muse, mutect2
- SOX17 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs756080176, COSV52024962; called by muse, mutect2, varscan2
- SPATA31E1 | c.2936C>A p.S979Y | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.633); catalogued as COSV57790219; called by muse, mutect2, varscan2
- SPTB | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 209/856 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.169); catalogued as rs138841945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SSTR4 | c.7G>C p.A3P | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV54798985; called by muse, mutect2, varscan2
- TCHH | c.5687G>A p.R1896H | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs757637538; called by muse, varscan2
- TINAG | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 86/359 reads (24%) | catalogued as COSV52513286, COSV99450709; called by muse, mutect2, varscan2
- TNRC18 | c.3499G>A p.E1167K | Missense Mutation (SNP) | VAF 134/420 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1402170727, COSV101269504; called by muse, mutect2, varscan2
- TNS3 | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100235996; called by muse, mutect2
- TRIM32 | c.440G>C p.R147P | Missense Mutation (SNP) | VAF 59/337 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs552938001; called by muse, mutect2, varscan2
- TRIM47 | c.620A>G p.Q207R | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.111); catalogued as rs774414286; called by muse, mutect2, varscan2
- TSHZ1 | c.1904A>G p.N635S (on ENST00000580243 / NM_001308210.2; = p.N590S on NM_005786.6) | Missense Mutation (SNP) | VAF 26/405 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs1486922015; called by muse, mutect2
- TTN | c.25378G>A p.V8460I (on ENST00000591111; = p.V7533I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 221/519 reads (43%) | PolyPhen benign (0); catalogued as rs376823283; ClinVar: likely benign / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.17772C>G p.S5924R (on ENST00000591111; = p.S4997R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 172/480 reads (36%) | PolyPhen probably damaging (0.961); catalogued as rs1015857991; called by muse, mutect2, varscan2
- TYR | c.1494G>C p.L498F | Missense Mutation (SNP) | VAF 161/978 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.48); catalogued as COSV99634058; called by muse, mutect2, varscan2
- UBXN2B | c.806T>C p.L269S | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477588334; called by muse, mutect2, varscan2
- UNC93A | c.1027C>A p.R343S | Missense Mutation (SNP) | VAF 56/554 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV57808676; called by muse, mutect2, varscan2
- WDFY4 | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 55/748 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV57431793; called by muse, mutect2
- WDFY4 | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 117/270 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1274113792; called by muse, mutect2, varscan2
- WDPCP | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 85/673 reads (13%) | catalogued as rs768036084, COSV99706838; called by muse, mutect2, varscan2
- WDR43 | c.1390G>T p.V464F | Missense Mutation (SNP) | VAF 35/361 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as rs779632583, COSV56099490, COSV56100294; called by muse, mutect2, varscan2
- WDR72 | c.2951A>C p.Q984P | Missense Mutation (SNP) | VAF 73/668 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs746882883; called by muse, mutect2, varscan2
- ZNF208 | c.2626C>A p.L876I | Missense Mutation (SNP) | VAF 96/771 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1381176752, COSV68107768; called by muse, mutect2, varscan2
- ZNF804B | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 30/269 reads (11%) | catalogued as COSV60826361; called by muse, mutect2, varscan2
- ZNF846 | c.1323A>T p.L441F | Missense Mutation (SNP) | VAF 102/393 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.329); catalogued as COSV101194324; called by muse, mutect2, varscan2
- ABCB1 | c.3335A>T p.H1112L | Missense Mutation (SNP) | VAF 129/693 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ACRV1 | c.651C>A p.C217* | Nonsense Mutation (SNP) | VAF 46/275 reads (17%) | called by muse, mutect2, varscan2
- ACSS1 | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, varscan2
- ADAMTS3 | c.1562G>C p.G521A | Missense Mutation (SNP) | VAF 66/376 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS6 | c.3199C>T p.Q1067* | Nonsense Mutation (SNP) | VAF 123/376 reads (33%) | called by muse, mutect2, varscan2
- ADCY8 | c.2666A>G p.H889R | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADCY8 | c.1130T>A p.V377E | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ADGRE3 | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 118/488 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADK | c.221A>G p.K74R (on ENST00000286621; = p.K57R on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/640 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- AFM | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by muse, mutect2
- AICDA | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 88/585 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AKT2 | c.1366+5G>A | Splice Region (SNP) | VAF 50/306 reads (16%) | called by muse, mutect2, varscan2
- AL117348.2 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 110/461 reads (24%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALOXE3 | c.816C>A p.H272Q | Missense Mutation (SNP) | VAF 189/588 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.9125C>A p.S3042Y | Missense Mutation (SNP) | VAF 90/285 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ANKRD11 | c.2792C>A p.P931H | Missense Mutation (SNP) | VAF 191/695 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ANKRD18A | c.822G>C p.M274I | Missense Mutation (SNP) | VAF 26/707 reads (4%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2
- ANKRD52 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARMC8 | c.528A>T p.K176N (on ENST00000469044 / NM_001363941.2; = p.K162N on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/770 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- ATP11A | c.2787C>G p.I929M | Missense Mutation (SNP) | VAF 70/437 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- BAIAP2 | c.527A>T p.E176V | Missense Mutation (SNP) | VAF 115/321 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BCAS3 | c.2266A>G p.T756A (on ENST00000390652 / NM_001353144.2; = p.T741A on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/718 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- BTNL2 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); called by muse, varscan2
- C16orf86 | c.875C>A p.S292* | Nonsense Mutation (SNP) | VAF 102/702 reads (15%) | called by muse, mutect2, varscan2
- C1QL2 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- C7 | c.1421T>C p.L474P | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CACNA1H | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.365T>C p.V122A | Missense Mutation (SNP) | VAF 56/329 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CAPRIN1 | c.780A>T p.E260D | Missense Mutation (SNP) | VAF 82/654 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- CARD19 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CCDC85A | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDH12 | c.1520T>C p.I507T | Missense Mutation (SNP) | VAF 112/567 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH22 | c.838+1G>A p.X280_splice | Splice Site (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- CDK14 | c.128G>T p.C43F (on ENST00000380050 / NM_001287135.2; = p.C25F on NM_012395.3) | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CEP350 | c.3358A>G p.T1120A | Missense Mutation (SNP) | VAF 100/349 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CFAP46 | c.7817C>A p.P2606Q | Missense Mutation (SNP) | VAF 140/294 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- CFHR1 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 233/1229 reads (19%) | called by muse, mutect2, varscan2
- CHAF1A | c.580G>C p.G194R | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CLIC6 | c.1059C>A p.D353E | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CNTN4 | c.117G>T p.L39F | Missense Mutation (SNP) | VAF 129/465 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- COL9A1 | c.1913T>C p.L638P | Missense Mutation (SNP) | VAF 83/1010 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2
- CPSF6 | c.452G>C p.G151A | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CRTAM | c.490+1G>A p.X164_splice | Splice Site (SNP) | VAF 42/213 reads (20%) | called by muse, mutect2, varscan2
- CSF3R | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 116/426 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CSNK1D | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 151/984 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK1G1 | c.806C>G p.T269S | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- CXCL10 | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- CXorf66 | c.623G>T p.R208M | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DAZAP1 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DCAF12 | c.580A>T p.S194C | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DENND4B | c.3854G>T p.S1285I | Missense Mutation (SNP) | VAF 120/579 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLL3 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- DNAH5 | c.12437C>A p.S4146Y | Missense Mutation (SNP) | VAF 183/1332 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DNAH5 | c.8131G>T p.G2711C | Missense Mutation (SNP) | VAF 106/841 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK4 | c.3124G>A p.V1042I | Missense Mutation (SNP) | VAF 41/420 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- DPF3 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 89/295 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPYS | c.318A>T p.K106N | Missense Mutation (SNP) | VAF 287/947 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DRP2 | c.407C>A p.A136D | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECEL1 | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 163/429 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.432G>A p.W144* | Nonsense Mutation (SNP) | VAF 167/473 reads (35%) | called by muse, mutect2, varscan2
- EIF2AK4 | c.3254C>T p.T1085I | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ELMO1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 128/657 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ELP1 | c.2507G>T p.C836F | Missense Mutation (SNP) | VAF 159/966 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ENOX2 | c.514G>C p.E172Q (on ENST00000338144 / NM_001382520.1; = p.E143Q on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- EPB41L3 | c.2304del p.R769Gfs*7 | Frame Shift Del (DEL) | VAF 72/275 reads (26%) | called by mutect2, pindel, varscan2
- EPB41L3 | c.839C>A p.A280E | Missense Mutation (SNP) | VAF 99/523 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- EXOC8 | c.505_525del p.V169_L175del | In Frame Del (DEL) | VAF 141/694 reads (20%) | called by mutect2, pindel, varscan2
- EYS | c.1460-2A>G p.X487_splice | Splice Site (SNP) | VAF 122/631 reads (19%) | called by mutect2, varscan2
- FAM102B | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM170B | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM221B | c.381C>A p.D127E | Missense Mutation (SNP) | VAF 1244/1548 reads (80%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAM241B | c.230del p.P77Rfs*13 | Frame Shift Del (DEL) | VAF 254/836 reads (30%) | called by mutect2, pindel, varscan2
- FAM47A | c.1915C>A p.H639N | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FAT3 | c.3022C>T p.L1008F | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.14778A>T p.Q4926H | Missense Mutation (SNP) | VAF 181/531 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- FBH1 | c.2458G>T p.G820C (on ENST00000362091 / NM_178150.3; = p.G871C on NM_032807.4) | Missense Mutation (SNP) | VAF 207/716 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- FCER2 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 78/289 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGF22 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- FREM2 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FSTL5 | c.2417T>G p.F806C | Missense Mutation (SNP) | VAF 115/399 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FYCO1 | c.599G>T p.S200I | Missense Mutation (SNP) | VAF 188/641 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GAK | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT15 | c.395_397del p.K132del | In Frame Del (DEL) | VAF 42/187 reads (22%) | called by mutect2, pindel, varscan2
- GLB1L3 | c.70T>C p.F24L | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLIS1 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GLRX5 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 71/418 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNAT3 | c.80C>A p.A27D | Missense Mutation (SNP) | VAF 46/950 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); called by muse, mutect2
- GOLGA6L6 | c.744+1G>T p.X248_splice | Splice Site (SNP) | VAF 43/215 reads (20%) | called by muse, mutect2, varscan2
- GPR37 | c.970A>G p.T324A | Missense Mutation (SNP) | VAF 94/603 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GPRC6A | c.2026T>C p.C676R | Missense Mutation (SNP) | VAF 83/517 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GREM2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 75/422 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); called by mutect2, varscan2
- GSTM2 | c.577A>C p.N193H | Missense Mutation (SNP) | VAF 108/297 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- HDAC9 | c.265-6C>T | Splice Region (SNP) | VAF 40/256 reads (16%) | called by muse, varscan2
- HGSNAT | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- HMCN2 | c.11074C>A p.P3692T | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- HPR | c.678G>C p.W226C | Missense Mutation (SNP) | VAF 151/532 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HS6ST2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 116/215 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ICE1 | c.1420A>G p.R474G | Missense Mutation (SNP) | VAF 53/469 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 121/1033 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ILDR2 | c.1573G>T p.D525Y | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- INPP4B | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 131/564 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IRX1 | c.656A>T p.D219V | Missense Mutation (SNP) | VAF 117/462 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGA8 | c.1445G>T p.R482I | Missense Mutation (SNP) | VAF 204/634 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KANK3 | c.1820T>A p.L607Q | Missense Mutation (SNP) | VAF 182/552 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.396); called by muse, varscan2
- KCNJ8 | c.716A>T p.E239V | Missense Mutation (SNP) | VAF 21/680 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNK3 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KISS1R | c.369+1G>T p.X123_splice | Splice Site (SNP) | VAF 70/445 reads (16%) | called by muse, mutect2, varscan2
- KLHL1 | c.1414G>T p.G472* | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- KRTAP5-1 | c.385A>T p.S129C | Missense Mutation (SNP) | VAF 120/353 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, varscan2
- LAMC3 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 102/451 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- LATS1 | c.2690G>A p.R897K | Missense Mutation (SNP) | VAF 72/739 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2
- LAYN | c.110-7_124del p.X37_splice (on ENST00000375615 / NM_001258390.1; = p.X29_splice on NM_178834.5) | Splice Site (DEL) | VAF 25/131 reads (19%) | called by mutect2, pindel
- LCN9 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- LRCH2 | c.1745A>G p.D582G | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- LRIT3 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- LRP1B | c.7475G>T p.R2492I | Missense Mutation (SNP) | VAF 107/350 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRC63 | c.689T>A p.V230D | Missense Mutation (SNP) | VAF 138/333 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- LRRIQ3 | c.1469G>A p.R490K | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRRIQ4 | c.1571T>A p.F524Y | Missense Mutation (SNP) | VAF 360/1059 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRK2 | c.875A>T p.H292L | Missense Mutation (SNP) | VAF 69/613 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- MALRD1 | c.6176A>T p.K2059M | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MAST2 | c.2012G>A p.G671D | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAVS | c.416G>T p.S139I | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MECR | c.580A>T p.S194C | Missense Mutation (SNP) | VAF 60/332 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, varscan2
- MED25 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MON2 | c.2501G>A p.W834* | Nonsense Mutation (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRTFA | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 170/558 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- MS4A18 | c.610G>C p.V204L (on ENST00000398983; = p.V206L on NM_001354471.1) | Missense Mutation (SNP) | VAF 139/566 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- MTUS2 | c.1993G>C p.V665L | Missense Mutation (SNP) | VAF 96/203 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MUC12 | c.13399G>A p.G4467R (on ENST00000379442; = p.G4324R on NM_001164462.1) | Missense Mutation (SNP) | VAF 70/1532 reads (5%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- MUC16 | c.12338C>G p.S4113* | Nonsense Mutation (SNP) | VAF 76/405 reads (19%) | called by muse, mutect2, varscan2
- MYBPC3 | c.1677G>T p.K559N | Missense Mutation (SNP) | VAF 62/441 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MYH13 | c.1937C>A p.S646Y | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MYNN | c.812A>C p.E271A | Missense Mutation (SNP) | VAF 76/998 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- NAP1L2 | c.705_707del p.E235del | In Frame Del (DEL) | VAF 38/122 reads (31%) | called by pindel, varscan2
- NCAPD3 | c.923T>A p.L308* | Nonsense Mutation (SNP) | VAF 16/334 reads (5%) | called by muse, mutect2
- NEK10 | c.3299C>G p.A1100G | Missense Mutation (SNP) | VAF 136/500 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- NEK3 | c.1433A>T p.D478V | Missense Mutation (SNP) | VAF 132/280 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP2 | c.2537+2T>C p.X846_splice | Splice Site (SNP) | VAF 182/993 reads (18%) | called by muse, mutect2, varscan2
- NOVA1 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 137/816 reads (17%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- NSD1 | c.3926del p.S1309Ifs*10 | Frame Shift Del (DEL) | VAF 130/548 reads (24%) | called by mutect2, pindel, varscan2
- OR1A2 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- OR2L2 | c.748T>C p.Y250H | Missense Mutation (SNP) | VAF 16/381 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR2M2 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 116/530 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- OR2T27 | c.868T>C p.Y290H | Missense Mutation (SNP) | VAF 183/1026 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- OR5B3 | c.748T>C p.Y250H | Missense Mutation (SNP) | VAF 184/640 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5H14 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- OR5T3 | c.571dup p.C191Lfs*2 | Frame Shift Ins (INS) | VAF 100/463 reads (22%) | called by mutect2, pindel, varscan2
- OR7D4 | c.862T>A p.F288I | Missense Mutation (SNP) | VAF 138/522 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- OR8D2 | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 41/340 reads (12%) | called by muse, mutect2, varscan2
- ORMDL3 | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OVCH1 | c.2567G>T p.G856V | Missense Mutation (SNP) | VAF 128/473 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDHA3 | c.456T>A p.F152L | Missense Mutation (SNP) | VAF 173/523 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- PCDHB10 | c.2353G>T p.G785C | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHGA7 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 79/472 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PDE1C | c.1398G>T p.R466S | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PDZD8 | c.337G>C p.A113P | Missense Mutation (SNP) | VAF 144/404 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PDZRN3 | c.1769G>C p.G590A | Missense Mutation (SNP) | VAF 162/463 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PGK2 | c.1144A>C p.K382Q | Missense Mutation (SNP) | VAF 44/1050 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.675); called by muse, mutect2
- PGM5 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 88/1512 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- PHOX2A | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 155/464 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIGO | c.1290G>C p.Q430H | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIK3R6 | c.103T>A p.W35R | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PPFIA2 | c.1306C>A p.H436N | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); called by muse, mutect2
- PROS1 | c.732A>G p.I244M | Missense Mutation (SNP) | VAF 26/375 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.3); called by muse, mutect2
- PROX1 | c.1607A>G p.H536R | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRPH | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 147/412 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PRRC2C | c.4649C>G p.P1550R (on ENST00000367742; = p.P1548R on NM_015172.4) | Missense Mutation (SNP) | VAF 46/359 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PTPN14 | c.3167T>G p.L1056W | Missense Mutation (SNP) | VAF 143/1112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRK | c.1900G>C p.V634L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- PYCR3 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 106/383 reads (28%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- RAB40AL | c.428C>G p.A143G | Missense Mutation (SNP) | VAF 222/437 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RABL3 | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 212/505 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RANBP3L | c.1024A>T p.I342F | Missense Mutation (SNP) | VAF 73/338 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RHAG | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 234/1081 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RHOH | c.120C>A p.N40K | Missense Mutation (SNP) | VAF 91/309 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RIPPLY2 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 121/345 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNASEL | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 124/661 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ROCK2 | c.2362G>T p.D788Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- RPS6KA2 | c.1541G>C p.C514S | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RYR2 | c.11857del p.H3953Ifs*4 | Frame Shift Del (DEL) | VAF 73/573 reads (13%) | called by mutect2, pindel, varscan2
- RYR3 | c.6817G>T p.E2273* (on ENST00000389232; = p.E2274* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 70/327 reads (21%) | called by muse, mutect2, varscan2
- SALL1 | c.3173C>G p.S1058C | Missense Mutation (SNP) | VAF 406/1523 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SAMD11 | c.1334G>C p.S445T | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, varscan2
- SBK3 | c.941G>T p.R314I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCIN | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 70/398 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SCN10A | c.2426T>C p.L809P | Missense Mutation (SNP) | VAF 111/385 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SCN4A | c.5008C>A p.P1670T | Missense Mutation (SNP) | VAF 90/490 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SEL1L2 | c.1848C>A p.D616E | Missense Mutation (SNP) | VAF 163/709 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SEL1L2 | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 59/454 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- SELP | c.1913C>A p.P638Q | Missense Mutation (SNP) | VAF 194/646 reads (30%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- SEMA3D | c.1414+1G>T p.X472_splice | Splice Site (SNP) | VAF 90/338 reads (27%) | called by muse, mutect2
- SEMA3D | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 88/340 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SETD1B | c.1891-2A>G p.X631_splice | Splice Site (SNP) | VAF 47/237 reads (20%) | called by muse, mutect2, varscan2
- SLC19A3 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 369/1119 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SLC35F1 | c.423A>T p.E141D | Missense Mutation (SNP) | VAF 68/310 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- SLC37A3 | c.1175G>C p.G392A | Missense Mutation (SNP) | VAF 80/764 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC38A5 | c.1383C>G p.N461K | Missense Mutation (SNP) | VAF 86/172 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SLC4A8 | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC5A5 | c.424-1G>A p.X142_splice | Splice Site (SNP) | VAF 158/880 reads (18%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.1504A>G p.K502E | Missense Mutation (SNP) | VAF 69/659 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SLCO1B1 | c.1648C>T p.L550F | Missense Mutation (SNP) | VAF 62/489 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SLCO1C1 | c.1088C>A p.T363N | Missense Mutation (SNP) | VAF 43/476 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- SLIT3 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMC1B | c.1427A>G p.E476G | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SMG8 | c.2630A>T p.E877V | Missense Mutation (SNP) | VAF 78/668 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- SOX1 | c.205A>T p.M69L | Missense Mutation (SNP) | VAF 336/716 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- SRCIN1 | c.2355C>G p.H785Q (on ENST00000621492; = p.H751Q on NM_025248.3) | Missense Mutation (SNP) | VAF 49/396 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SSRP1 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 115/400 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ST7 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 215/789 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- STYXL2 | c.3332G>A p.R1111K | Missense Mutation (SNP) | VAF 34/838 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2
- SYNE1 | c.1492C>A p.L498I (on ENST00000367255 / NM_182961.4; = p.L505I on NM_033071.3) | Missense Mutation (SNP) | VAF 57/471 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SYT1 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 132/588 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TACC1 | c.1392G>T p.T464= | Splice Region (SNP) | VAF 222/655 reads (34%) | called by muse, mutect2, varscan2
- TBC1D15 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- TBCD | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 80/277 reads (29%) | called by muse, mutect2, varscan2
- TBX22 | c.924del p.F308Lfs*18 | Frame Shift Del (DEL) | VAF 155/463 reads (33%) | called by mutect2, pindel, varscan2
- TECTB | c.410+1G>C p.X137_splice | Splice Site (SNP) | VAF 92/259 reads (36%) | called by muse, mutect2, varscan2
- TEX55 | c.665C>G p.P222R | Missense Mutation (SNP) | VAF 60/485 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- THBS2 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 63/660 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TLR7 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- TMC5 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 66/505 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- TMEM132C | c.1614C>A p.S538R | Missense Mutation (SNP) | VAF 91/594 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- TMEM132C | c.2971C>A p.Q991K | Missense Mutation (SNP) | VAF 91/284 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- TMEM8B | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 76/2241 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- TOR1B | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 139/811 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TPGS2 | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- TPM2 | c.241-2A>G p.X81_splice | Splice Site (SNP) | VAF 134/2556 reads (5%) | called by muse, mutect2
- TRIM42 | c.915C>A p.D305E | Missense Mutation (SNP) | VAF 126/1886 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- TRIM56 | c.512_519dup p.G174Sfs*24 | Frame Shift Ins (INS) | VAF 26/104 reads (25%) | called by mutect2, varscan2
- TRIM72 | c.837G>T p.K279N | Missense Mutation (SNP) | VAF 124/429 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- TRPM7 | c.4985A>T p.Y1662F | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- TSPEAR | c.922+1G>T p.X308_splice | Splice Site (SNP) | VAF 211/488 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.74256G>T p.L24752F (on ENST00000591111; = p.L17328F on NM_003319.4) | Missense Mutation (SNP) | VAF 541/1280 reads (42%) | PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- TTN | c.69852G>A p.M23284I (on ENST00000591111; = p.M15860I on NM_003319.4) | Missense Mutation (SNP) | VAF 76/142 reads (54%) | PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TUBB8B | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 170/710 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TUSC3 | c.799-1G>T p.X267_splice | Splice Site (SNP) | VAF 80/707 reads (11%) | called by muse, mutect2, varscan2
- USH2A | c.14633G>C p.C4878S | Missense Mutation (SNP) | VAF 228/1232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USH2A | c.7167C>G p.S2389R | Missense Mutation (SNP) | VAF 125/489 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP24 | c.7662A>T p.K2554N | Missense Mutation (SNP) | VAF 99/391 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- VEPH1 | c.2345G>C p.R782P | Missense Mutation (SNP) | VAF 261/1166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VMP1 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 45/440 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWDE | c.2595G>T p.R865S | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2
- YWHAZ | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 133/941 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ZBTB22 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 216/765 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF107 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF214 | c.256A>T p.T86S | Missense Mutation (SNP) | VAF 37/472 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- ZNF276 | c.783G>A p.W261* (on ENST00000443381 / NM_001113525.2; = p.W186* on NM_152287.4) | Nonsense Mutation (SNP) | VAF 127/652 reads (19%) | called by muse, mutect2, varscan2
- ZNF320 | c.1184G>T p.S395I | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.343); called by mutect2, varscan2
- ZNF536 | c.1367G>C p.G456A | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF98 | c.45T>A p.F15L | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ZSWIM6 | c.1604T>G p.I535S | Missense Mutation (SNP) | VAF 149/515 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- AASDH | c.1623A>C p.I541= | Silent (SNP) | VAF 55/289 reads (19%) | called by muse, mutect2, varscan2
- ABCA10 | c.2652G>A p.A884= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as rs375537071; called by muse, mutect2, varscan2
- ABCC6 | c.3150G>A p.K1050= | Silent (SNP) | VAF 129/819 reads (16%) | called by muse, mutect2, varscan2
- ACER1 | c.750G>T p.V250= | Silent (SNP) | VAF 40/170 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.1380T>C p.R460= | Silent (SNP) | VAF 86/240 reads (36%) | catalogued as rs769786865, COSV66859459; called by muse, mutect2, varscan2
- ANKFN1 | c.1575T>A p.L525= | Silent (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- ATG4C | c.1278T>C p.Y426= | Silent (SNP) | VAF 28/199 reads (14%) | called by muse, mutect2, varscan2
- ATP10A | c.3300G>T p.V1100= | Silent (SNP) | VAF 55/189 reads (29%) | called by muse, mutect2, varscan2
- ATXN1L | c.360A>T p.P120= | Silent (SNP) | VAF 57/370 reads (15%) | called by muse, mutect2, varscan2
- CCL18 | c.72T>C p.G24= | Silent (SNP) | VAF 38/265 reads (14%) | called by muse, mutect2, varscan2
- CD2 | c.819T>G p.P273= | Silent (SNP) | VAF 40/496 reads (8%) | called by muse, mutect2
- CD209 | c.390G>T p.L130= | Silent (SNP) | VAF 461/1436 reads (32%) | called by muse, mutect2, varscan2
- CDH19 | c.1359G>T p.S453= | Silent (SNP) | VAF 66/217 reads (30%) | catalogued as COSV50955714, COSV50960953; called by muse, mutect2, varscan2
- CEP112 | c.873T>C p.N291= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- CEP192 | c.7326A>C p.P2442= | Silent (SNP) | VAF 24/448 reads (5%) | called by muse, mutect2
- CFAP65 | c.4539C>T p.S1513= | Silent (SNP) | VAF 110/341 reads (32%) | called by muse, mutect2, varscan2
- CKLF | c.399G>A p.L133= (on ENST00000264001 / NM_016951.4; = p.L48= on NM_016326.3) | Silent (SNP) | VAF 109/1050 reads (10%) | called by muse, mutect2, varscan2
- COX15 | c.711C>T p.S237= | Silent (SNP) | VAF 251/697 reads (36%) | catalogued as rs1224352719; called by muse, mutect2, varscan2
- CPB1 | c.1194C>T p.C398= | Silent (SNP) | VAF 124/814 reads (15%) | catalogued as rs538633141, COSV99294462; called by muse, mutect2, varscan2
- CRACD | c.2679A>G p.K893= | Silent (SNP) | VAF 68/230 reads (30%) | called by muse, varscan2
- CSMD1 | c.9759C>A p.S3253= (on ENST00000520002; = p.S3252= on NM_033225.6) | Silent (SNP) | VAF 84/857 reads (10%) | called by muse, mutect2
- CSMD3 | c.9249T>C p.D3083= (on ENST00000297405 / NM_001363185.1; = p.D2914= on NM_052900.3) | Silent (SNP) | VAF 218/1345 reads (16%) | called by muse, mutect2, varscan2
- CSRNP3 | c.126A>T p.P42= | Silent (SNP) | VAF 162/362 reads (45%) | called by muse, mutect2, varscan2
- DNAH11 | c.10410C>T p.N3470= | Silent (SNP) | VAF 226/942 reads (24%) | catalogued as rs746707590, COSV100175988; called by muse, mutect2, varscan2
- EEPD1 | c.1299A>G p.L433= | Silent (SNP) | VAF 105/294 reads (36%) | called by muse, mutect2, varscan2
- ESPN | c.192G>T p.A64= | Silent (SNP) | VAF 260/511 reads (51%) | catalogued as rs372705054; called by muse, mutect2, varscan2
- FAM135B | c.1155C>A p.L385= | Silent (SNP) | VAF 149/488 reads (31%) | catalogued as COSV99424189; called by muse, mutect2, varscan2
- FAM71F1 | c.405A>T p.P135= | Silent (SNP) | VAF 73/208 reads (35%) | called by muse, mutect2, varscan2
- FAT3 | c.11031C>A p.V3677= | Silent (SNP) | VAF 61/327 reads (19%) | called by muse, mutect2, varscan2
- FAT4 | c.7605A>G p.E2535= | Silent (SNP) | VAF 118/439 reads (27%) | catalogued as COSV58687630; called by muse, mutect2, varscan2
- FIGNL2 | c.771G>A p.P257= | Silent (SNP) | VAF 69/180 reads (38%) | catalogued as rs757808380; called by muse, mutect2, varscan2
- FRMD1 | c.261G>T p.A87= | Silent (SNP) | VAF 163/594 reads (27%) | catalogued as COSV51961470, COSV99349574; called by muse, mutect2, varscan2
- FTMT | c.45G>A p.S15= | Silent (SNP) | VAF 51/367 reads (14%) | catalogued as COSV58419570; called by muse, mutect2, varscan2
- GAS2 | c.540T>A p.S180= | Silent (SNP) | VAF 97/428 reads (23%) | called by muse, mutect2, varscan2
- GPR173 | c.447C>A p.T149= | Silent (SNP) | VAF 120/239 reads (50%) | called by muse, mutect2, varscan2
- GRIN2B | c.3030C>G p.P1010= | Silent (SNP) | VAF 58/386 reads (15%) | called by muse, mutect2, varscan2
- H2BC17 | c.6C>A p.P2= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100377414, COSV58152007; called by muse, varscan2
- IGSF9B | c.1329T>C p.A443= | Silent (SNP) | VAF 43/247 reads (17%) | called by muse, mutect2, varscan2
- IQSEC3 | c.2220A>T p.A740= (on ENST00000538872 / NM_001170738.2; = p.A437= on NM_015232.1) | Silent (SNP) | VAF 26/202 reads (13%) | called by muse, mutect2, varscan2
- KDM5A | c.2169A>G p.E723= | Silent (SNP) | VAF 180/457 reads (39%) | called by muse, mutect2, varscan2
- KIAA0408 | c.1431C>A p.T477= | Silent (SNP) | VAF 80/317 reads (25%) | called by muse, mutect2, varscan2
- KIF5A | c.138A>G p.P46= | Silent (SNP) | VAF 204/822 reads (25%) | called by muse, mutect2, varscan2
- KLHL32 | c.1206A>T p.A402= | Silent (SNP) | VAF 193/612 reads (32%) | called by muse, mutect2, varscan2
- KNDC1 | c.216C>T p.A72= | Silent (SNP) | VAF 238/590 reads (40%) | catalogued as rs1289547474; called by muse, varscan2
- LATS1 | c.2835G>T p.V945= | Silent (SNP) | VAF 57/564 reads (10%) | called by muse, mutect2, varscan2
- LCE4A | c.252C>T p.G84= | Silent (SNP) | VAF 52/207 reads (25%) | catalogued as rs746801973; called by muse, mutect2, varscan2
- LMTK2 | c.3069C>T p.P1023= | Silent (SNP) | VAF 97/401 reads (24%) | catalogued as rs148046091; called by muse, mutect2, varscan2
- LMTK3 | c.777C>T p.S259= | Silent (SNP) | VAF 95/278 reads (34%) | called by muse, mutect2, varscan2
- MAP3K12 | c.1665C>T p.S555= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- MINAR1 | c.573C>A p.S191= | Silent (SNP) | VAF 146/366 reads (40%) | called by muse, mutect2, varscan2
- MROH7 | c.714G>C p.G238= | Silent (SNP) | VAF 113/578 reads (20%) | called by muse, mutect2, varscan2
- MTUS2 | c.1926C>T p.P642= | Silent (SNP) | VAF 183/428 reads (43%) | called by muse, mutect2, varscan2
- MUC5AC | c.1134G>A p.T378= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs1451526996; called by muse, mutect2, varscan2
- NNMT | c.255C>T p.D85= | Silent (SNP) | VAF 110/867 reads (13%) | catalogued as COSV100248759; called by muse, mutect2, varscan2
- NPFFR1 | c.1053C>T p.R351= | Silent (SNP) | VAF 55/160 reads (34%) | called by muse, mutect2, varscan2
- NPHS2 | c.189G>A p.T63= | Silent (SNP) | VAF 113/549 reads (21%) | catalogued as rs764283921; called by muse, mutect2, varscan2
- NPR2 | c.1461G>A p.L487= | Silent (SNP) | VAF 276/5718 reads (5%) | called by muse, mutect2
- NR3C2 | c.1731A>G p.L577= | Silent (SNP) | VAF 80/333 reads (24%) | called by muse, mutect2, varscan2
- OR10K2 | c.552C>A p.V184= | Silent (SNP) | VAF 149/589 reads (25%) | called by muse, mutect2, varscan2
- OR1C1 | c.264C>A p.G88= | Silent (SNP) | VAF 102/339 reads (30%) | called by muse, mutect2, varscan2
- OR2A2 | c.936G>T p.T312= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as COSV68871198; called by muse, varscan2
- OR2C3 | c.792C>A p.A264= | Silent (SNP) | VAF 226/746 reads (30%) | called by muse, mutect2, varscan2
- OR2T27 | c.273C>A p.A91= | Silent (SNP) | VAF 73/837 reads (9%) | called by muse, mutect2
- OR2W3 | c.901C>T p.L301= | Silent (SNP) | VAF 46/246 reads (19%) | catalogued as rs780525144; called by muse, varscan2
- OR4K1 | c.438T>C p.S146= | Silent (SNP) | VAF 124/843 reads (15%) | called by muse, mutect2, varscan2
- OR51F1 | c.843C>A p.V281= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV58580732; called by muse, mutect2
- OR5J2 | c.93C>T p.F31= | Silent (SNP) | VAF 61/346 reads (18%) | catalogued as rs531423583; called by muse, mutect2, varscan2
- OR5L2 | c.345G>T p.L115= | Silent (SNP) | VAF 74/456 reads (16%) | catalogued as COSV65725298; called by muse, mutect2, varscan2
- OR7G3 | c.897G>A p.K299= | Silent (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2
- PCDH11Y | c.435C>A p.A145= (on ENST00000400457 / NM_032973.2; = p.A134= on NM_032971.3) | Silent (SNP) | VAF 90/452 reads (20%) | called by muse, mutect2, varscan2
- PCDHA6 | c.75G>A p.K25= | Silent (SNP) | VAF 91/232 reads (39%) | catalogued as COSV65358501; called by muse, mutect2, varscan2
- PDIA2 | c.1227G>A p.V409= | Silent (SNP) | VAF 53/141 reads (38%) | called by muse, mutect2, varscan2
- PDZD2 | c.7026T>C p.F2342= | Silent (SNP) | VAF 139/421 reads (33%) | called by muse, mutect2, varscan2
- PGBD1 | c.1173C>T p.T391= | Silent (SNP) | VAF 18/460 reads (4%) | called by muse, mutect2
- PKN1 | c.1905G>T p.R635= | Silent (SNP) | VAF 41/230 reads (18%) | called by muse, mutect2, varscan2
- POU3F1 | c.660G>C p.A220= | Silent (SNP) | VAF 24/131 reads (18%) | called by muse, mutect2, varscan2
- PTPRD | c.636C>T p.S212= | Silent (SNP) | VAF 162/616 reads (26%) | catalogued as rs369295626, COSV61974688; called by muse, mutect2, varscan2
- RFC2 | c.981A>T p.I327= (on ENST00000055077 / NM_181471.3; = p.I293= on NM_002914.4) | Silent (SNP) | VAF 115/477 reads (24%) | called by muse, mutect2, varscan2
- SALL1 | c.2463A>G p.L821= | Silent (SNP) | VAF 56/932 reads (6%) | called by muse, mutect2
- SCN2A | c.4902C>A p.G1634= | Silent (SNP) | VAF 279/799 reads (35%) | called by muse, mutect2, varscan2
- SCN3B | c.427C>T p.L143= | Silent (SNP) | VAF 129/638 reads (20%) | called by muse, mutect2, varscan2
- SCN7A | c.690G>T p.L230= | Silent (SNP) | VAF 127/305 reads (42%) | called by muse, mutect2, varscan2
- SEL1L2 | c.1047T>C p.A349= | Silent (SNP) | VAF 57/453 reads (13%) | called by muse, mutect2, varscan2
- SHROOM3 | c.2835C>T p.D945= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1167534607; called by muse, varscan2
- SIPA1L1 | c.3441G>T p.R1147= | Silent (SNP) | VAF 181/760 reads (24%) | called by muse, mutect2, varscan2
- SLC1A3 | c.48G>A p.E16= | Silent (SNP) | VAF 98/309 reads (32%) | called by muse, mutect2, varscan2
- SLC24A5 | c.336T>C p.T112= | Silent (SNP) | VAF 32/854 reads (4%) | called by muse, mutect2
- SLC7A7 | c.471C>T p.A157= | Silent (SNP) | VAF 38/312 reads (12%) | called by muse, mutect2, varscan2
- SORCS1 | c.2703C>T p.T901= | Silent (SNP) | VAF 82/282 reads (29%) | called by muse, mutect2, varscan2
- STOML1 | c.649C>T p.L217= | Silent (SNP) | VAF 108/239 reads (45%) | called by muse, mutect2, varscan2
- TENM2 | c.1449C>A p.I483= (on ENST00000518659 / NM_001122679.2; = p.I251= on NM_001080428.3) | Silent (SNP) | VAF 187/573 reads (33%) | called by muse, varscan2
- TMC4 | c.1953G>A p.G651= (on ENST00000617472 / NM_001145303.3; = p.G645= on NM_144686.4) | Silent (SNP) | VAF 68/276 reads (25%) | called by muse, mutect2, varscan2
- TRBV5-1 | c.120G>T p.L40= | Silent (SNP) | VAF 60/315 reads (19%) | called by muse, mutect2, varscan2
- TRIO | c.3253C>T p.L1085= | Silent (SNP) | VAF 108/509 reads (21%) | called by muse, mutect2, varscan2
- TRPM3 | c.2211C>T p.A737= (on ENST00000357533 / NM_001366142.2; = p.A580= on NM_020952.6) | Silent (SNP) | VAF 70/333 reads (21%) | called by muse, mutect2, varscan2
- TTC7A | c.1083G>T p.V361= | Silent (SNP) | VAF 33/330 reads (10%) | called by muse, mutect2, varscan2
- TTN | c.83232C>T p.A27744= (on ENST00000591111; = p.A20320= on NM_003319.4) | Silent (SNP) | VAF 629/1341 reads (47%) | called by muse, mutect2, varscan2
- UNC13B | c.4215T>C p.F1405= | Silent (SNP) | VAF 118/1020 reads (12%) | called by muse, mutect2, varscan2
- VGLL2 | c.690C>A p.V230= | Silent (SNP) | VAF 108/369 reads (29%) | called by muse, mutect2, varscan2
- WASHC4 | c.1836C>G p.V612= | Silent (SNP) | VAF 53/500 reads (11%) | catalogued as rs760811611; called by muse, mutect2, varscan2
- WDR17 | c.3237G>T p.V1079= | Silent (SNP) | VAF 97/493 reads (20%) | called by muse, mutect2, varscan2
- ZNF175 | c.1008A>T p.I336= | Silent (SNP) | VAF 37/265 reads (14%) | called by muse, mutect2, varscan2
- ZNF212 | c.288G>T p.V96= | Silent (SNP) | VAF 162/627 reads (26%) | called by muse, mutect2, varscan2
- ZNF717 | c.2094G>C p.P698= | Silent (SNP) | VAF 34/298 reads (11%) | called by muse, varscan2
- A1BG | c.70+10G>A | Intron (SNP) | VAF 56/280 reads (20%) | catalogued as rs749283525; called by muse, mutect2, varscan2
- ABL2 | c.158-9610C>A | Intron (SNP) | VAF 139/822 reads (17%) | catalogued as COSV61019505; called by muse, mutect2, varscan2
- AC016582.1 | chr19:37824328 C>T | 3'Flank (SNP) | VAF 17/488 reads (3%) | called by muse, mutect2
- AC107023.1 | n.26-9244C>A | Intron (SNP) | VAF 51/237 reads (22%) | called by muse, mutect2, varscan2
- AC244197.3 | c.-1728G>T | 5'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- ACAA2 | chr18:49814061 G>T | 5'Flank (SNP) | VAF 106/216 reads (49%) | called by muse, mutect2
- AL353804.4 | chrX:73824005 G>T | 5'Flank (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- ANO4 | c.-95A>G | 5'UTR (SNP) | VAF 46/341 reads (13%) | catalogued as rs768834845; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499669 G>A | 5'Flank (SNP) | VAF 56/151 reads (37%) | called by muse, mutect2, varscan2
- ARL8B | c.-110del | 5'UTR (DEL) | VAF 149/351 reads (42%) | called by mutect2, pindel, varscan2
- ATP7B | c.*22G>T | 3'UTR (SNP) | VAF 383/824 reads (46%) | called by muse, mutect2, varscan2
- CDON | c.1852-29T>A | Intron (SNP) | VAF 143/841 reads (17%) | called by muse, mutect2, varscan2
- CLEC18B | c.785-151G>T | Intron (SNP) | VAF 96/1894 reads (5%) | called by muse, mutect2
- CLU | c.*1233G>C | 3'UTR (SNP) | VAF 41/428 reads (10%) | called by muse, mutect2, varscan2
- COL9A1 | c.976-26C>G | Intron (SNP) | VAF 43/489 reads (9%) | called by muse, mutect2
- CXCL12 | c.266+818C>G | Intron (SNP) | VAF 143/402 reads (36%) | called by muse, mutect2, varscan2
- DACH2 | c.1240+2812T>A | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- DCHS2 | n.1483del | RNA (DEL) | VAF 124/415 reads (30%) | called by mutect2, pindel, varscan2
- DERA | c.32-194A>T | Intron (SNP) | VAF 46/323 reads (14%) | called by muse, mutect2, varscan2
- ECT2L | c.*21G>C | 3'UTR (SNP) | VAF 74/638 reads (12%) | called by muse, mutect2, varscan2
- EFCAB11 | c.411-39715del | Intron (DEL) | VAF 156/465 reads (34%) | called by mutect2, varscan2
- ELAPOR2 | c.2169+430G>C | Intron (SNP) | VAF 104/671 reads (15%) | called by muse, mutect2, varscan2
- ENAM | c.535-45C>T | Intron (SNP) | VAF 64/531 reads (12%) | catalogued as rs768112277; called by muse, mutect2, varscan2
- FAM221A | chr7:23680170 C>A | 5'Flank (SNP) | VAF 154/599 reads (26%) | called by muse, mutect2
- FLT1 | c.2117-10948C>A | Intron (SNP) | VAF 225/715 reads (31%) | called by muse, varscan2
- FMO9P | n.277G>T | RNA (SNP) | VAF 115/541 reads (21%) | called by muse, mutect2, varscan2
- GATM | c.-58G>T | 5'UTR (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- GDAP1 | c.*1894dup | 3'UTR (INS) | VAF 24/216 reads (11%) | called by mutect2, varscan2
- GRM8 | c.1357+68084T>A | Intron (SNP) | VAF 84/429 reads (20%) | called by muse, mutect2, varscan2
- GTPBP1 | chr22:38736212 C>T | 3'Flank (SNP) | VAF 21/74 reads (28%) | catalogued as rs748133609; called by muse, mutect2, varscan2
- GVINP1 | n.7319A>T | RNA (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- HS6ST1 | c.-3C>A | 5'UTR (SNP) | VAF 12/161 reads (7%) | called by muse, mutect2
- HSPA7 | n.876C>T | RNA (SNP) | VAF 233/820 reads (28%) | catalogued as rs762912458; called by muse, mutect2, varscan2
- LHX2 | c.-1G>T | 5'UTR (SNP) | VAF 63/367 reads (17%) | catalogued as rs1198542108; called by muse, mutect2, varscan2
- LINC02453 | n.22A>G | RNA (SNP) | VAF 26/399 reads (7%) | called by muse, mutect2
- MCM2 | c.-15G>A | 5'UTR (SNP) | VAF 211/964 reads (22%) | catalogued as rs1413317782; called by muse, mutect2, varscan2
- MIR622 | n.31G>A | RNA (SNP) | VAF 249/649 reads (38%) | called by muse, mutect2, varscan2
- MLIP | c.64-9876C>A | Intron (SNP) | VAF 134/546 reads (25%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40561357 C>T | 5'Flank (SNP) | VAF 58/503 reads (12%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.1172+43T>A | Intron (SNP) | VAF 376/748 reads (50%) | called by muse, mutect2, varscan2
- NLRP3 | c.*2A>C | 3'UTR (SNP) | VAF 135/1178 reads (11%) | called by muse, mutect2, varscan2
- OCA2 | c.*14A>G | 3'UTR (SNP) | VAF 280/1349 reads (21%) | called by muse, mutect2, varscan2
- OPRM1 | c.-453T>A | 5'UTR (SNP) | VAF 46/164 reads (28%) | called by muse, mutect2, varscan2
- PCBP3 | c.717+16G>A | Intron (SNP) | VAF 120/428 reads (28%) | called by muse, varscan2
- PDE4DIP | c.637-7158G>T | Intron (SNP) | VAF 111/605 reads (18%) | called by muse, mutect2, varscan2
- PFKFB1 | c.-1G>A | 5'UTR (SNP) | VAF 101/228 reads (44%) | catalogued as rs776849018; called by muse, mutect2, varscan2
- PHACTR1 | c.664+2220G>T | Intron (SNP) | VAF 201/820 reads (25%) | called by muse, mutect2, varscan2
- POM121 | chr7:72949439 G>A | 3'Flank (SNP) | VAF 64/396 reads (16%) | called by muse, mutect2, varscan2
- PPM1F | c.206+33G>C | Intron (SNP) | VAF 54/212 reads (25%) | called by muse, mutect2, varscan2
- PRAME | c.22-1728C>T | Intron (SNP) | VAF 79/287 reads (28%) | called by muse, mutect2, varscan2
- PSME1 | c.459+16C>G | Intron (SNP) | VAF 20/415 reads (5%) | called by muse, mutect2
- PTPRQ | c.6042-687C>A | Intron (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- RN7SL319P | chr15:75786798 G>T | 3'Flank (SNP) | VAF 115/271 reads (42%) | called by muse, mutect2, varscan2
- SEMG2 | c.-6A>T | 5'UTR (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- SLC26A9 | c.*142C>A | 3'UTR (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- SLC39A3 | chr19:2732239 C>G | 3'Flank (SNP) | VAF 45/304 reads (15%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088441 C>T | 3'Flank (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- SNORD116-18 | chr15:25088795 A>T | 3'Flank (SNP) | VAF 227/994 reads (23%) | called by muse, mutect2, varscan2
- SYMPK | c.2893+251G>C | Intron (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- TBC1D32 | c.*432A>T | 3'UTR (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- TMEM132E | chr17:34578928 A>G | 5'Flank (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- TMEM183B | n.1039G>T | RNA (SNP) | VAF 157/791 reads (20%) | called by muse, varscan2
- TRIM67 | c.1045-9840G>T | Intron (SNP) | VAF 75/337 reads (22%) | called by muse, mutect2, varscan2
- UBR7 | c.*1600G>A | 3'UTR (SNP) | VAF 46/350 reads (13%) | called by muse, mutect2, varscan2
- UQCRB | c.19+12G>C | Intron (SNP) | VAF 159/1455 reads (11%) | catalogued as rs557037218; called by muse, mutect2, varscan2
